Somatic mutation profile of tumor specimen MMRF_1775_1_BM_CD138pos (aliquot MMRF_1775_1_BM_CD138pos_T1_KBS5U_K11331) from MMRF case MMRF_1775, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.0 years (19,740 days).
Specimen MMRF_1775_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42a9b1f7-2e84-4af8-841d-3417b427b734.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1775_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1775_1_PB_Whole_C2_KBS5U_K11332; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b428e5a5-0b4e-4027-9ad1-0104da091caa

The open-access MAF lists 66 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 16, Silent 8, Intron 7, Frame Shift Del 4, 3'Flank 2, Splice Site 1, Nonsense Mutation 1, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs571638097, COSV54100847, COSV99511856; called by muse, mutect2, varscan2
- FOXP2 | c.598-1G>C p.X200_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as rs752704782, COSV63481967; ClinVar: uncertain significance; called by mutect2, varscan2
- HK3 | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs192416700, COSV99459162; called by muse, mutect2
- IGHV2-70 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs377422798; called by muse, mutect2, varscan2
- IGLV3-1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs144850905; called by muse, mutect2, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, mutect2, varscan2
- NPAS3 | c.1495G>A p.D499N (on ENST00000356141 / NM_001164749.2; = p.D467N on NM_022123.3) | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs1479621400, COSV100640278; called by muse, mutect2
- PAAF1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs751629541, COSV60157158; called by muse, mutect2, varscan2
- PCNX2 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); catalogued as rs572250857; called by muse, mutect2, varscan2
- PGR | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.742); catalogued as rs749564230, COSV99677589; called by muse, mutect2, varscan2
- RBM14 | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs1219206865; called by muse, mutect2, varscan2
- SEZ6L2 | c.1108G>A p.V370I (on ENST00000308713 / NM_001114099.3; = p.V300I on NM_012410.4) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs771572181, COSV58099177; called by muse, mutect2, varscan2
- SHISA9 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.759); catalogued as rs1160840228, COSV101428455; called by muse, mutect2, varscan2
- SURF4 | c.524T>G p.F175C | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368036527; called by muse, mutect2
- TOP3B | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376446617; called by muse, mutect2, varscan2
- ACE2 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AKIP1 | c.80A>C p.E27A | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCHS2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HSD3B1 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IL5RA | c.116_117del p.K39Sfs*16 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- JAG1 | c.2906T>A p.M969K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LRP12 | c.799del p.Y267Mfs*22 | Frame Shift Del (DEL) | VAF 72/206 reads (35%) | called by mutect2, varscan2
- MTFR1L | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NOL6 | c.2857del p.Q953Kfs*32 | Frame Shift Del (DEL) | VAF 146/294 reads (50%) | called by mutect2, pindel, varscan2
- PLA2G15 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PURA | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); called by muse, mutect2
- RNF133 | c.669G>A p.W223* | Nonsense Mutation (SNP) | VAF 27/222 reads (12%) | called by muse, mutect2, varscan2
- SHANK2 | c.5414del p.E1805Gfs*26 | Frame Shift Del (DEL) | VAF 177/705 reads (25%) | called by mutect2, pindel, varscan2
- TAF5 | c.856A>T p.T286S | Missense Mutation (SNP) | VAF 141/346 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEKT1 | c.1087_1095del p.K363_L365del | In Frame Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- CSH2 | c.135C>T p.R45= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs753437650, COSV61081296; called by muse, mutect2, varscan2
- DCUN1D5 | c.465A>G p.R155= | Silent (SNP) | VAF 25/263 reads (10%) | called by muse, mutect2, varscan2
- GPR39 | c.783G>A p.T261= | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as rs1280709293; called by muse, mutect2, varscan2
- LILRA5 | c.207G>A p.G69= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as COSV56643018, COSV56644217; called by muse, mutect2, varscan2
- MLST8 | c.159C>T p.D53= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as rs768505491; called by muse, mutect2, varscan2
- OPCML | c.951C>A p.V317= | Silent (SNP) | VAF 53/146 reads (36%) | called by muse, mutect2, varscan2
- TEK | c.1983A>T p.I661= | Silent (SNP) | VAF 69/258 reads (27%) | called by muse, mutect2, varscan2
- TRDV3 | c.96T>C p.S32= | Silent (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.*606dup | 3'UTR (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- C5orf24 | c.*757del | 3'UTR (DEL) | VAF 57/172 reads (33%) | called by mutect2, pindel, varscan2
- CCL28 | c.*1485T>C | 3'UTR (SNP) | VAF 68/116 reads (59%) | called by muse, mutect2, varscan2
- CLN3 | c.388+36G>A | Intron (SNP) | VAF 26/159 reads (16%) | catalogued as rs375789794; called by muse, mutect2, varscan2
- CSNK1G1 | c.*5077T>G | 3'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- CTAG2 | chrX:154655219 A>C | 5'Flank (SNP) | VAF 31/35 reads (89%) | called by muse, mutect2, varscan2
- DIO2 | c.*1761A>C | 3'UTR (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- ERBB4 | c.*4058T>G | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- GRAMD1B | c.*1391C>A | 3'UTR (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- H2AZ2 | c.325+453C>T | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as rs1004838498; called by muse, mutect2
- HSPB1P1 | n.55C>T | RNA (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+264A>T | Intron (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- KCNC4 | c.*1115C>T | 3'UTR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- KNTC1 | c.5742-74C>T | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- MAP3K2 | chr2:127304697 del A | 3'Flank (DEL) | VAF 59/157 reads (38%) | catalogued as rs955141810; called by mutect2, pindel, varscan2
- MTRR | c.*976_*979del | 3'UTR (DEL) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- NWD2 | c.*303T>C | 3'UTR (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- PLXDC1 | c.*2056C>T | 3'UTR (SNP) | VAF 55/142 reads (39%) | catalogued as rs1447167662, COSV59550187; called by muse, mutect2, varscan2
- RIC3 | c.*8C>T | 3'UTR (SNP) | VAF 111/372 reads (30%) | called by muse, mutect2, varscan2
- RNASEH2C | c.172+79G>A | Intron (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- SASH1 | c.*352C>T | 3'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- SEC24D | c.2496+46A>G | Intron (SNP) | VAF 33/86 reads (38%) | called by mutect2, varscan2
- SERPINE2 | c.*698T>C | 3'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as rs1002056915; called by muse, mutect2, varscan2
- STAT1 | c.*1054C>T | 3'UTR (SNP) | VAF 16/109 reads (15%) | catalogued as rs971028087; called by muse, mutect2, varscan2
- TAB1 | chr22:39436888 A>C | 3'Flank (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- TF | c.2063-197G>A | Intron (SNP) | VAF 9/18 reads (50%) | catalogued as rs370778991; called by muse, varscan2
- UBXN4 | c.*619dup | 3'UTR (INS) | VAF 4/45 reads (9%) | catalogued as rs1188586351; called by muse*, pindel, varscan2*
